Somatic mutation profile of tumor specimen TARGET-50-PAJPDC-02A (aliquot TARGET-50-PAJPDC-02A-01D) from TARGET case TARGET-50-PAJPDC, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: female; Vital status: Alive; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 8.0 years (2,904 days).
Specimen TARGET-50-PAJPDC-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1d14d9c-fbdf-4871-be89-29b96254ca8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAJPDC-10A (Blood Derived Normal), aliquot TARGET-50-PAJPDC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10da7bea-e122-41aa-a246-c128bb23508f

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 12, Silent 3, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASB5 | c.769G>C p.A257P | Missense Mutation (SNP) | VAF 213/576 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56669233, COSV56674827; called by muse, mutect2, varscan2
- CARD10 | c.1814G>A p.R605Q | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.042); catalogued as rs753304481, COSV52654931; called by muse, mutect2, varscan2
- CCER1 | c.659C>T p.T220M | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs371760411, COSV62646253; called by muse, mutect2, varscan2
- CDC73 | c.1560-1G>T p.X520_splice | Splice Site (SNP) | VAF 387/705 reads (55%) | catalogued as COSV66465583; called by muse, mutect2, varscan2
- DNHD1 | c.13267G>A p.V4423M | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1422055452, COSV54432019; called by muse, mutect2, varscan2
- GTF2H3 | c.128T>C p.V43A | Missense Mutation (SNP) | VAF 169/694 reads (24%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.998); catalogued as COSV57460367; called by muse, mutect2, varscan2
- HDAC4 | c.1547G>A p.R516Q | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.738); catalogued as rs201982913, COSV61876134; called by muse, varscan2
- KHDRBS3 | c.762C>G p.Y254* | Nonsense Mutation (SNP) | VAF 13/27 reads (48%) | catalogued as COSV63415713; called by muse, mutect2, varscan2
- MTMR3 | c.2233C>G p.L745V | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs760984166, COSV60302512; called by muse, mutect2, varscan2
- TACR1 | c.1166G>T p.R389L | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV59485522; called by muse, mutect2
- COPE | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- KLHL20 | c.95A>G p.K32R | Missense Mutation (SNP) | VAF 91/336 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAMDC4 | c.2682C>A p.H894Q (on ENST00000445819; = p.H815Q on NM_206920.3) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.996); called by muse, varscan2
- TMEM232 | c.1349G>A p.G450E | Missense Mutation (SNP) | VAF 45/824 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GOLGA4 | c.294C>T p.S98= | Silent (SNP) | VAF 155/205 reads (76%) | called by muse, mutect2, varscan2
- IGKV3D-11 | c.39C>G p.L13= | Silent (SNP) | VAF 40/201 reads (20%) | called by muse, mutect2, varscan2
- MAST1 | c.954G>A p.T318= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs751945653, COSV52242751; called by muse, mutect2, varscan2
